Somatic mutation profile of tumor specimen 0DFHEM from CCDI case PBBSBG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebrum; Age at diagnosis: 9.4 years (3,437 days).
Specimen 0DFHEM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54b669eb-c8cb-47e3-a553-1de1040f322b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFHEN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8331be8-e364-4484-b449-cfd3db8db630

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF451 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 251/1335 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs767171327; called by muse, mutect2, varscan2
- OR5L2 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 78/1462 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2
- RPUSD1 | c.33C>A p.I11= | Silent (SNP) | VAF 12/306 reads (4%) | catalogued as COSV50100303; called by muse, mutect2
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- GTF2A1 | c.*23A>T | 3'UTR (SNP) | VAF 21/566 reads (4%) | called by muse, mutect2
